Somatic mutation profile of cancer-model specimen HCM-BROD-0594-C43-85M (Adherent Cell Line, passage 10; aliquot HCM-BROD-0594-C43-85M-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0594-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.4 years (27,524 days).
Specimen HCM-BROD-0594-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e631d7f1-5f9c-482f-8cd5-8f619e542607.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0594-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0594-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f460393-1616-4b5a-8f4a-f500777ce7d0

The open-access MAF lists 3,555 somatic variants for this specimen: 2,238 protein-altering or splice-affecting, 1,191 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,046, Silent 1,191, Nonsense Mutation 118, Intron 84, Splice Region 35, Frame Shift Del 18, RNA 13, 3'UTR 12, Splice Site 12, 5'UTR 7, 3'Flank 6, 5'Flank 4.

Variants (750 of 3,555; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A3 | c.2491G>A p.E831K (on ENST00000545399 / NM_001256214.2; = p.E818K on NM_152296.5) | Missense Mutation (SNP) | VAF 182/464 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs587777771, CM140738, COSV57489768; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 192/323 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1555767914, COSV100802407; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EDNRB | c.871C>T p.R291* (on ENST00000377211 / NM_001201397.1; = p.R201* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 277/372 reads (74%) | catalogued as rs104894391, CM020406; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 114/246 reads (46%) | catalogued as rs1303773212, COSV70342690; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- NPHP1 | c.1036C>T p.R346* (on ENST00000393272 / NM_207181.4; = p.R347* on NM_000272.5) | Nonsense Mutation (SNP) | VAF 97/221 reads (44%) | catalogued as rs765263671, CM080456, COSV57206565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 305/423 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61964623; called by muse, mutect2, varscan2
- AADACL3 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 184/390 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100206811; called by muse, mutect2, varscan2
- AASDH | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs772133272; called by muse, mutect2, varscan2
- ABCA7 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 487/779 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54025463, COSV54032840; called by muse, mutect2, varscan2
- ABCA8 | c.1568C>A p.S523* | Nonsense Mutation (SNP) | VAF 130/355 reads (37%) | catalogued as rs866764495; called by muse, mutect2, varscan2
- ABCB11 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 119/224 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55594493, COSV55595120; called by muse, mutect2, varscan2
- ABCB5 | c.2335C>T p.Q779* (on ENST00000404938 / NM_001163941.2; = p.Q334* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 143/301 reads (48%) | catalogued as COSV51718861; called by muse, mutect2, varscan2
- ABCB8 | c.857C>T p.S286F (on ENST00000297504 / NM_001282291.2; = p.S269F on NM_007188.5) | Missense Mutation (SNP) | VAF 319/577 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52505217; called by muse, mutect2, varscan2
- ABCC11 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 367/368 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs377008966, COSV62322643; called by muse, mutect2, varscan2
- ABCC3 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 283/501 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53324526; called by muse, mutect2, varscan2
- ABCG1 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV59204181; called by muse, mutect2, varscan2
- ABCG8 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 137/381 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs769649113, COSV55392165; called by muse, mutect2, varscan2
- AC126283.2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 164/164 reads (100%) | catalogued as COSV67097984, COSV67099039; called by muse, mutect2, varscan2
- AC131160.1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 276/576 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.287); catalogued as rs756273693, COSV100226128; called by muse, varscan2
- ACAD10 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 127/322 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as rs766574091; called by muse, mutect2, varscan2
- ACAN | c.2935G>A p.G979R | Missense Mutation (SNP) | VAF 300/910 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779442875; called by muse, varscan2
- ACE | c.3886C>T p.Q1296* | Nonsense Mutation (SNP) | VAF 233/599 reads (39%) | catalogued as rs1162756119; called by muse, mutect2, varscan2
- ACMSD | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 189/325 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51609694; called by muse, mutect2, varscan2
- ACOT11 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 235/487 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs750295708, COSV100989447; called by muse, mutect2, varscan2
- ACSM5 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866780401; called by muse, mutect2, varscan2
- ADAM11 | c.2111G>T p.W704L | Missense Mutation (SNP) | VAF 186/378 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99567883; called by muse, mutect2, varscan2
- ADAM2 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 276/506 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55870177, COSV99697341; called by muse, mutect2, varscan2
- ADAM21 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as rs866624996; called by muse, mutect2, varscan2
- ADAM22 | c.2627C>T p.S876F (on ENST00000265727 / NM_001324420.2; = p.S840F on NM_016351.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/357 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs201785658; called by muse, mutect2, varscan2
- ADAM7 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 204/494 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV51536126; called by muse, mutect2, varscan2
- ADAMTS20 | c.3643G>A p.D1215N | Missense Mutation (SNP) | VAF 156/343 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV67126412; called by muse, mutect2, varscan2
- ADAMTS20 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 179/334 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.373); catalogued as COSV67130927, COSV67131880; called by muse, mutect2, varscan2
- ADAMTS20 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV67125970; called by muse, mutect2, varscan2
- ADAMTS4 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 231/449 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs3134667, COSV63489947; called by muse, mutect2, varscan2
- ADAMTS9 | c.2933G>A p.G978D | Missense Mutation (SNP) | VAF 122/392 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs868693196; called by muse, mutect2, varscan2
- ADGRB3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 91/165 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs766735540, COSV65381042; called by muse, mutect2, varscan2
- ADGRB3 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1363049892, COSV65419101; called by muse, mutect2, varscan2
- ADGRB3 | c.3653G>A p.R1218K | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53247337, COSV99485893; called by muse, mutect2, varscan2
- ADGRE1 | c.2256G>A p.W752* | Nonsense Mutation (SNP) | VAF 132/354 reads (37%) | catalogued as rs759823059; called by muse, mutect2, varscan2
- ADGRF4 | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 167/500 reads (33%) | catalogued as COSV51957562; called by muse, mutect2, varscan2
- ADGRG4 | c.8002G>A p.V2668I | Missense Mutation (SNP) | VAF 62/62 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV99796270; called by muse, mutect2, varscan2
- ADGRG7 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 165/271 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56299253; called by muse, mutect2, varscan2
- ADGRL2 | c.3275G>A p.R1092Q (on ENST00000370717 / NM_001366005.1; = p.R1079Q on NM_012302.4) | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as rs767737569, COSV54654551; called by muse, mutect2, varscan2
- ADGRL4 | c.1521G>A p.W507* | Nonsense Mutation (SNP) | VAF 172/371 reads (46%) | catalogued as COSV66063072; called by muse, mutect2, varscan2
- AGMAT | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 268/572 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.153); catalogued as rs1213386987; called by muse, mutect2, varscan2
- AGTR2 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs138066085; called by muse, mutect2, varscan2
- AHNAK2 | c.7169C>T p.P2390L | Missense Mutation (SNP) | VAF 290/588 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768667423; called by muse, mutect2
- AIF1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 142/438 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.483); catalogued as COSV100559070; called by muse, mutect2, varscan2
- AIRE | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 180/352 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs966636123, COSV52392733; called by muse, mutect2, varscan2
- AK9 | c.3319C>T p.L1107F | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58138188, COSV58141295; called by muse, mutect2, varscan2
- AK9 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs370294605; called by muse, mutect2, varscan2
- AKAP11 | c.3949C>T p.P1317S | Missense Mutation (SNP) | VAF 340/449 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99214519; called by muse, mutect2, varscan2
- AKAP6 | c.6532G>A p.E2178K | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.395); catalogued as rs982411521; called by muse, mutect2, varscan2
- AKR1D1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 134/227 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as rs1173927246, COSV54340322; called by muse, varscan2
- AL590132.1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 226/526 reads (43%) | SIFT tolerated, low confidence (0.38); catalogued as rs954104044; called by muse, mutect2, varscan2
- ALDH16A1 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 332/610 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1336722001; called by muse, mutect2, varscan2
- ALDH1A2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 147/258 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV99990755; called by muse, mutect2, varscan2
- ALMS1 | c.12356C>T p.S4119F | Missense Mutation (SNP) | VAF 101/261 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100044087; called by muse, mutect2, varscan2
- ALPG | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 171/478 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV99779288; called by muse, mutect2, varscan2
- ALPK3 | c.3287C>T p.S1096F | Missense Mutation (SNP) | VAF 504/864 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99362112; called by muse, mutect2, varscan2
- AMPH | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 214/422 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781682680, COSV57737654; called by muse, mutect2, varscan2
- AMY2A | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 205/463 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs148507365, COSV101340692, COSV70214788; called by muse, mutect2, varscan2
- ANGPT4 | c.581A>G p.Q194R | Missense Mutation (SNP) | VAF 190/272 reads (70%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101124938; called by muse, mutect2, varscan2
- ANK1 | c.4924G>A p.E1642K | Missense Mutation (SNP) | VAF 217/512 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as rs372606605, COSV55897961; called by muse, mutect2, varscan2
- ANK1 | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 270/549 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV55885737; called by muse, mutect2, varscan2
- ANK3 | c.13105C>T p.R4369W (on ENST00000280772 / NM_001320874.2; = p.R993W on NM_001149.3) | Missense Mutation (SNP) | VAF 132/288 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs556782173, COSV55057446; called by muse, mutect2, varscan2
- ANK3 | c.9982C>T p.P3328S | Missense Mutation (SNP) | VAF 147/292 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs148029765, COSV55060820; called by muse, mutect2, varscan2
- ANK3 | c.6071C>T p.S2024F | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV55060523; called by muse, mutect2
- ANK3 | c.5384C>T p.P1795L | Missense Mutation (SNP) | VAF 128/266 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.656); catalogued as rs571449073; called by muse, mutect2, varscan2
- ANKFN1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 105/268 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as rs750597107; called by muse, mutect2, varscan2
- ANKFN1 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 142/282 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1483775741, COSV59457299; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7003C>T p.P2335S | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs1324125991; called by muse, mutect2, varscan2
- ANKRD24 | c.1225G>C p.V409L | Missense Mutation (SNP) | VAF 251/421 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV53675149; called by muse, mutect2, varscan2
- ANKRD30A | c.1294G>A p.A432T (on ENST00000611781; = p.A376T on NM_052997.2) | Missense Mutation (SNP) | VAF 100/299 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as rs1443657019, COSV64618400; called by muse, mutect2, varscan2
- ANKRD30A | c.1521G>A p.M507I (on ENST00000611781; = p.M451I on NM_052997.2) | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as rs564319804, COSV64614781; called by muse, mutect2, varscan2
- ANKRD30B | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs772268065, COSV62813891; called by muse, varscan2
- ANKRD60 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 255/361 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs899988816, COSV64518559; called by muse, varscan2
- ANO2 | c.790G>A p.E264K (on ENST00000356134 / NM_001278597.3; = p.E268K on NM_001278596.3) | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV59047961; called by muse, mutect2, varscan2
- ANO3 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 200/326 reads (61%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.889); catalogued as rs1458612996, COSV56788908; called by muse, mutect2, varscan2
- ANO4 | c.1446G>A p.M482I (on ENST00000392977 / NM_001286615.2; = p.M447I on NM_178826.4) | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV54612995; called by muse, mutect2, varscan2
- ANO5 | c.1999C>T p.L667F | Missense Mutation (SNP) | VAF 103/279 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.35); catalogued as COSV61086995; called by muse, mutect2, varscan2
- ANPEP | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 200/579 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs1476692994; called by muse, mutect2, varscan2
- ANPEP | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 311/533 reads (58%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1456553395, COSV55589443; called by muse, mutect2, varscan2
- AP2A2 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 342/508 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100173207; called by muse, mutect2, varscan2
- APBA3 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 368/600 reads (61%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as rs1225711386; called by muse, varscan2
- APC | c.4067C>T p.S1356L | Missense Mutation (SNP) | VAF 218/357 reads (61%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV57325773, COSV57330189, COSV57333960; called by muse, mutect2, varscan2
- APOL1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 259/446 reads (58%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs369288414; called by muse, mutect2, varscan2
- APOL3 | c.880G>A p.E294K (on ENST00000349314 / NM_145640.2; = p.E223K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 492/492 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV62579136; called by muse, mutect2, varscan2
- ARAP3 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 115/316 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1465420579, COSV53354616; called by muse, mutect2, varscan2
- ARHGAP26 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 267/442 reads (60%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as COSV50829840; called by muse, mutect2, varscan2
- ARHGEF5 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 167/895 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99283283; called by muse, mutect2, varscan2
- ARL6IP6 | c.472A>T p.I158L | Missense Mutation (SNP) | VAF 109/303 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs182329683, COSV58444072; called by muse, mutect2, varscan2
- ARMC5 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 426/427 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.371); catalogued as rs1467735332; called by muse, mutect2, varscan2
- ARPIN | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 285/551 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1245139234; called by muse, mutect2, varscan2
- ARSJ | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 220/220 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV59537913; called by muse, mutect2, varscan2
- ASB16 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 214/376 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs573677324; called by muse, mutect2, varscan2
- ASTN2 | c.3113G>A p.G1038E (on ENST00000313400 / NM_001365069.1; = p.G987E on NM_014010.5) | Missense Mutation (SNP) | VAF 144/275 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748277908, COSV55998169, COSV56002019; called by muse, mutect2, varscan2
- ATP11C | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 89/89 reads (100%) | catalogued as COSV100557613; called by muse, mutect2, varscan2
- ATP1A3 | c.2859G>A p.K953= (on ENST00000545399 / NM_001256214.2; = p.K940= on NM_152296.5) | Splice Region (SNP) | VAF 177/309 reads (57%) | catalogued as COSV100132338; called by muse, mutect2, varscan2
- ATP4A | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 163/384 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as rs1459787937, COSV52869527; called by muse, mutect2, varscan2
- ATP6V0D2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 124/374 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV99572023; called by muse, mutect2, varscan2
- ATP8B4 | c.2885G>A p.G962E | Missense Mutation (SNP) | VAF 149/383 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52723464; called by muse, mutect2, varscan2
- AXL | c.1616G>A p.G539E (on ENST00000301178 / NM_021913.5; = p.G530E on NM_001699.6) | Missense Mutation (SNP) | VAF 136/364 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56564783; called by muse, mutect2, varscan2
- B4GALNT3 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 192/562 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs567579470, COSV56752097; called by muse, mutect2, varscan2
- BAIAP2L1 | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 252/501 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV50059341; called by muse, mutect2, varscan2
- BCAS1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 87/349 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV65090147; called by muse, mutect2, varscan2
- BCL11A | c.1007C>T p.S336F (on ENST00000335712 / NM_001365609.1; = p.S370F on NM_018014.4) | Missense Mutation (SNP) | VAF 120/316 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs984726946; called by muse, mutect2, varscan2
- BDKRB1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 188/385 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145002930, COSV53706253; called by muse, mutect2, varscan2
- BEND3 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs373701775; called by muse, mutect2
- BEND4 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 294/295 reads (100%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.057); catalogued as COSV101549699; called by muse, mutect2, varscan2
- BMP5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 102/337 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63701018; called by muse, mutect2, varscan2
- BRAF | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 122/229 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs397507472, COSV56068050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs146031731, CM160118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTG4 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV63637412; called by muse, mutect2, varscan2
- BTNL3 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 278/278 reads (100%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV61564826; called by muse, mutect2, varscan2
- BTNL3 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 116/321 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV61564844; called by muse, mutect2, varscan2
- C10orf120 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 126/272 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs756538058, COSV100271618; called by muse, mutect2, varscan2
- C10orf71 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 106/106 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60505818; called by muse, mutect2, varscan2
- C10orf71 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.278); catalogued as rs1467149505, COSV100110093; called by muse, mutect2, varscan2
- C10orf71 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 128/129 reads (99%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as rs758980501, COSV60509997; called by muse, mutect2, varscan2
- C11orf40 | n.142G>A | Splice Region (SNP) | VAF 66/173 reads (38%) | catalogued as COSV56890552; called by muse, mutect2, varscan2
- C1QTNF4 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 223/680 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs1466620981; called by muse, mutect2, varscan2
- C1R | c.1640G>A p.G547E (on ENST00000536053 / NM_001354346.2; = p.G533E on NM_001733.7) | Missense Mutation (SNP) | VAF 309/474 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.567); catalogued as COSV73382815; called by muse, mutect2, varscan2
- C1orf94 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 239/372 reads (64%) | catalogued as rs1557475925; called by muse, mutect2, varscan2
- C20orf144 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 187/749 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs997208461; called by muse, mutect2, varscan2
- C2orf16 | c.3115G>A p.D1039N | Missense Mutation (SNP) | VAF 172/304 reads (57%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs754428308, COSV62673723; called by muse, mutect2, varscan2
- C2orf81 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 198/340 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as rs1225754891; called by muse, mutect2, varscan2
- C3orf20 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 240/428 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as rs1166049309; called by muse, mutect2
- C6 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 163/668 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV99667795; called by muse, mutect2, varscan2
- C7 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 177/238 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs977493333, COSV57471713; called by muse, varscan2
- C8A | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 201/416 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1483234568, COSV63484731; called by muse, mutect2, varscan2
- C8B | c.90C>T p.S30= | Splice Region (SNP) | VAF 172/362 reads (48%) | catalogued as rs758163769; called by muse, varscan2
- CACNA1E | c.3524C>T p.P1175L | Missense Mutation (SNP) | VAF 122/350 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62391236; called by muse, mutect2, varscan2
- CACNA1F | c.5510C>T p.S1837F | Missense Mutation (SNP) | VAF 152/153 reads (99%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV59904536; called by muse, mutect2, varscan2
- CACNA1S | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62936125; called by muse, mutect2, varscan2
- CADPS2 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 134/258 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs773480913, COSV57351573; called by muse, mutect2, varscan2
- CALHM3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 162/346 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.809); catalogued as rs751696710; called by muse, mutect2, varscan2
- CAP2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 93/298 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs762449193; called by muse, mutect2, varscan2
- CAPN13 | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 150/346 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as rs558380156, COSV54431295; called by muse, mutect2, varscan2
- CAPN3 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 187/354 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58820789; called by muse, mutect2, varscan2
- CARNS1 | c.2377G>A p.G793R | Missense Mutation (SNP) | VAF 468/889 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs749238189, COSV100322225; called by muse, mutect2, varscan2
- CATSPER2 | c.1486C>T p.R496* (on ENST00000321596 / NM_001282309.3; = p.R498* on NM_172095.4) | Nonsense Mutation (SNP) | VAF 187/631 reads (30%) | catalogued as rs377026307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPERB | c.3010C>T p.L1004F | Missense Mutation (SNP) | VAF 93/181 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV56422881; called by muse, mutect2, varscan2
- CBX2 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 271/599 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1428652993; called by muse, mutect2, varscan2
- CBX8 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 445/906 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs752624120; called by muse, mutect2
- CCDC105 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 192/320 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV52963394; called by muse, mutect2, varscan2
- CCDC141 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs747242213, COSV55382394; called by muse, mutect2, varscan2
- CCDC190 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 222/491 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.077); catalogued as COSV63362763; called by muse, mutect2, varscan2
- CCDC73 | c.315G>A p.K105= | Splice Region (SNP) | VAF 47/171 reads (27%) | catalogued as COSV58799502; called by muse, mutect2
- CCDC88C | c.3629G>A p.G1210E | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101105505; called by muse, mutect2, varscan2
- CCR9 | c.384G>A p.M128I (on ENST00000357632 / NM_031200.3; = p.M116I on NM_006641.4) | Missense Mutation (SNP) | VAF 240/365 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62940607; called by muse, mutect2, varscan2
- CD101 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 222/465 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1053045019; called by muse, mutect2, varscan2
- CD163 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 240/361 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63131336; called by muse, mutect2, varscan2
- CD1E | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as COSV63770627; called by muse, mutect2, varscan2
- CD22 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 151/376 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1298147775; called by muse, mutect2, varscan2
- CD27 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV56950184; called by muse, mutect2, varscan2
- CD38 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 175/176 reads (99%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV56889215; called by muse, mutect2, varscan2
- CD5L | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 205/320 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0.202); catalogued as rs1350559311; called by muse, mutect2, varscan2
- CDC123 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as rs1353855260; called by muse, mutect2, varscan2
- CDC42BPG | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 192/490 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867829277; called by muse, mutect2, varscan2
- CDH12 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 326/451 reads (72%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs770584780, COSV66385717; called by muse, mutect2, varscan2
- CDH13 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 220/221 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774928488; called by muse, mutect2, varscan2
- CDH17 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 199/305 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs755346799; called by muse, mutect2
- CDH18 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 108/451 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99933587; called by muse, mutect2, varscan2
- CDH23 | c.3843G>A p.M1281I | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV99823575; called by muse, mutect2, varscan2
- CDH23 | c.7138C>T p.P2380S | Missense Mutation (SNP) | VAF 175/381 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99823332; called by muse, mutect2, varscan2
- CDH26 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54842958; called by muse, mutect2, varscan2
- CDH4 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 153/695 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV64641612, COSV64643972; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 237/325 reads (73%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by muse, mutect2, varscan2
- CDHR2 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 150/389 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99990842; called by muse, mutect2, varscan2
- CEACAM20 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 224/369 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); catalogued as COSV57603041; called by muse, mutect2, varscan2
- CELSR1 | c.4925C>T p.T1642I | Missense Mutation (SNP) | VAF 134/395 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1288070949; called by muse, mutect2, varscan2
- CELSR2 | c.7913C>T p.S2638F | Missense Mutation (SNP) | VAF 235/505 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV54766536; called by muse, mutect2, varscan2
- CEP164 | c.3784C>T p.H1262Y | Missense Mutation (SNP) | VAF 216/218 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54046563; called by muse, varscan2
- CFAP221 | c.2182C>T p.L728F | Missense Mutation (SNP) | VAF 171/306 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.184); catalogued as rs1429107163; called by muse, mutect2, varscan2
- CFAP46 | c.922A>G p.I308V | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.071); catalogued as COSV63953759; called by muse, mutect2, varscan2
- CFAP74 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 216/434 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs1420420512; called by muse, mutect2, varscan2
- CFAP94 | c.1798G>A p.A600T (on ENST00000320267 / NM_001352064.2; = p.A606T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57230325; called by muse, mutect2, varscan2
- CFB | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 209/570 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as rs1291066881; called by muse, mutect2, varscan2
- CFTR | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 193/429 reads (45%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as rs397508822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFTR | c.3890C>T p.S1297F | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50055472; called by muse, mutect2, varscan2
- CGNL1 | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 159/294 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs748686101, COSV55570841; called by muse, mutect2, varscan2
- CHD3 | c.4972G>A p.G1658R (on ENST00000330494 / NM_001005273.3; = p.G1717R on NM_001005271.3) | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1248242661; called by muse, mutect2, varscan2
- CHD5 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 344/721 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52412020; called by muse, mutect2, varscan2
- CHD7 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 105/190 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1405371608; called by muse, mutect2, varscan2
- CHD7 | c.5623C>T p.P1875S | Missense Mutation (SNP) | VAF 167/280 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs762351985, COSV71108182; called by muse, mutect2, varscan2
- CHD8 | c.3337C>T p.R1113C (on ENST00000646647 / NM_001170629.2; = p.R834C on NM_020920.4) | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749785996; called by muse, mutect2, varscan2
- CHGB | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 141/409 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as COSV99081176; called by muse, mutect2, varscan2
- CHL1 | c.1313G>A p.G438E (on ENST00000397491 / NM_001253387.1; = p.G454E on NM_006614.4) | Missense Mutation (SNP) | VAF 123/302 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56606743; called by muse, mutect2, varscan2
- CHPF2 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 248/428 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1291202356; called by muse, mutect2, varscan2
- CIB2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 377/788 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs780146135; called by muse, mutect2, varscan2
- CILP | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 197/417 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201483229; called by muse, mutect2, varscan2
- CLCN1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 126/348 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58373130; called by muse, varscan2
- CLDN6 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 144/535 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV58509216; called by muse, mutect2, varscan2
- CLEC3A | c.205G>A p.E69K (on ENST00000651443; = p.E60K on NM_005752.6) | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV55219916; called by muse, mutect2, varscan2
- CLSTN3 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 164/461 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs755463631; called by muse, mutect2, varscan2
- CNGB3 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 142/234 reads (61%) | SIFT tolerated (0.8); PolyPhen benign (0.066); catalogued as COSV60699177; called by muse, mutect2, varscan2
- CNGB3 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 128/319 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as rs759584325; called by muse, mutect2, varscan2
- CNR2 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 289/464 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770828039; called by muse, mutect2, varscan2
- CNTN4 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 159/262 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as rs750294828, COSV61873461; called by muse, mutect2, varscan2
- CNTN5 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 164/165 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54285848; called by muse, mutect2, varscan2
- CNTNAP2 | c.1058G>T p.R353M | Missense Mutation (SNP) | VAF 168/303 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100665319, COSV62202488; called by muse, mutect2, varscan2
- CNTNAP4 | c.3026C>T p.S1009F | Missense Mutation (SNP) | VAF 69/70 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56702461; called by muse, mutect2, varscan2
- COL11A1 | c.2261G>A p.G754D | Missense Mutation (SNP) | VAF 201/421 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616110; called by muse, mutect2, varscan2
- COL11A2 | c.2272G>A p.E758K (on ENST00000341947 / NM_080680.3; = p.E651K on NM_080679.2) | Missense Mutation (SNP) | VAF 123/393 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs1304713056, COSV59499234; called by muse, mutect2, varscan2
- COL12A1 | c.2921C>T p.S974L | Missense Mutation (SNP) | VAF 127/247 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1308564004, COSV59395583; called by muse, mutect2, varscan2
- COL14A1 | c.5303G>A p.G1768D | Missense Mutation (SNP) | VAF 110/292 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as COSV52865798; called by muse, mutect2, varscan2
- COL16A1 | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 197/599 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54713244; called by muse, mutect2, varscan2
- COL17A1 | c.465G>A p.W155* | Nonsense Mutation (SNP) | VAF 114/238 reads (48%) | catalogued as rs1228451285; called by muse, mutect2, varscan2
- COL19A1 | c.2050C>T p.L684F | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765477557; called by muse, mutect2, varscan2
- COL19A1 | c.3302C>T p.A1101V | Missense Mutation (SNP) | VAF 67/108 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs753501507, COSV59577484; called by muse, mutect2, varscan2
- COL1A2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 222/442 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV51960202; called by muse, varscan2
- COL21A1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368730001; called by muse, varscan2
- COL22A1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 203/613 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249474608; called by muse, mutect2, varscan2
- COL24A1 | c.3862G>A p.G1288R | Missense Mutation (SNP) | VAF 141/298 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768681059; called by muse, mutect2, varscan2
- COL3A1 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 132/233 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58581677; called by muse, mutect2, varscan2
- COL3A1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV58596953; called by muse, mutect2, varscan2
- COL3A1 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58582876; called by muse, mutect2, varscan2
- COL3A1 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 184/310 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs759565407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 388/516 reads (75%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.936); catalogued as rs1402878630, COSV101011106; called by muse, mutect2, varscan2
- COL4A4 | c.3605C>T p.P1202L | Missense Mutation (SNP) | VAF 117/343 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.419); catalogued as rs779182761; called by muse, mutect2, varscan2
- COL4A5 | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 114/114 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs867265684; called by muse, mutect2, varscan2
- COL5A3 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 277/485 reads (57%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs771247699; called by muse, mutect2, varscan2
- COL6A3 | c.7627C>T p.L2543F | Missense Mutation (SNP) | VAF 224/395 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99796317; called by muse, mutect2
- COL7A1 | c.6016G>A p.G2006S | Missense Mutation (SNP) | VAF 244/710 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034798; called by muse, mutect2, varscan2
- COL7A1 | c.5710G>A p.G1904S | Missense Mutation (SNP) | VAF 346/538 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1357729432; called by muse, mutect2, varscan2
- COL9A1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 111/216 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1464239976, COSV61831024; called by muse, mutect2, varscan2
- COL9A3 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 615/855 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs748114912; called by muse, mutect2, varscan2
- COQ8A | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 224/372 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV64657571; called by muse, mutect2, varscan2
- CORO7 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 144/444 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1372322168; called by muse, mutect2, varscan2
- CPNE9 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV56069323; called by muse, mutect2, varscan2
- CPOX | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 117/446 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as rs938112157; called by muse, mutect2, varscan2
- CRYBG1 | c.4801G>A p.D1601N | Missense Mutation (SNP) | VAF 106/230 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as COSV64815014; called by muse, mutect2, varscan2
- CRYBG1 | c.5417C>T p.S1806F | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64811836; called by muse, mutect2, varscan2
- CSMD2 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 339/569 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53966299; called by muse, mutect2, varscan2
- CSMD2 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 152/301 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as rs1350135389; called by muse, mutect2
- CSMD2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 103/348 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53922489; called by muse, mutect2, varscan2
- CSMD3 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.999); catalogued as COSV52155228, COSV52161078; called by muse, mutect2, varscan2
- CSPG4 | c.3566A>T p.Q1189L | Missense Mutation (SNP) | VAF 313/608 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs760737016; called by muse, mutect2, varscan2
- CSRNP1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 308/455 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as rs150285879, COSV56189255; called by muse, mutect2, varscan2
- CT55 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 77/77 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV52278577; called by muse, mutect2, varscan2
- CTAGE1 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV101194676; called by muse, mutect2, varscan2
- CTCFL | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 366/494 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1187038024; called by muse, varscan2
- CTCFL | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 239/305 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54771935; called by muse, varscan2
- CTNNB1 | c.2119C>T p.L707F | Missense Mutation (SNP) | VAF 166/258 reads (64%) | SIFT tolerated (0.7); PolyPhen benign (0.137); catalogued as rs770804258, COSV100846071; called by muse, mutect2, varscan2
- CTSS | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs764417853, COSV64566046; called by muse, mutect2, varscan2
- CUX2 | c.3944C>T p.P1315L | Missense Mutation (SNP) | VAF 353/530 reads (67%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55646639; called by muse, varscan2
- CUX2 | c.3979C>T p.P1327S | Missense Mutation (SNP) | VAF 186/556 reads (33%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs1427959865, COSV99921165; called by muse, varscan2
- CWC27 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 74/183 reads (40%) | catalogued as rs747744168, COSV66885021; called by muse, mutect2, varscan2
- CYB5R4 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.394); catalogued as rs531779325, COSV63752383; called by muse, mutect2, varscan2
- CYP19A1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 98/247 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53057841; called by muse, mutect2, varscan2
- CYP2F1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 151/244 reads (62%) | catalogued as rs1349532357, COSV58527253; called by muse, mutect2, varscan2
- CYP3A5 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 129/263 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV56118310; called by muse, mutect2, varscan2
- CYP4B1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 282/558 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as COSV54722954; called by muse, mutect2, varscan2
- CYP4F11 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 200/358 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs1182851073; called by muse, mutect2, varscan2
- CYP4F3 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 196/336 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763337637; called by muse, mutect2, varscan2
- CYP4Z1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 140/281 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1206792114, COSV61964908; called by muse, mutect2, varscan2
- CYTIP | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 148/385 reads (38%) | catalogued as rs371815413, COSV51633532; called by muse, mutect2, varscan2
- DAB2IP | c.215C>T p.P72L (on ENST00000408936; = p.P44L on NM_032552.3) | Missense Mutation (SNP) | VAF 146/259 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763394734; called by muse, mutect2, varscan2
- DBF4B | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 286/705 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs770361509, COSV59261012; called by muse, mutect2, varscan2
- DBNL | c.1129C>T p.R377C (on ENST00000448521 / NM_001014436.3; = p.R378C on NM_014063.7) | Missense Mutation (SNP) | VAF 259/525 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1307332395, COSV99803898; called by muse, mutect2, varscan2
- DBX2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 194/415 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375287819, COSV60339154; called by muse, mutect2, varscan2
- DCAF8L2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 126/128 reads (98%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.486); catalogued as COSV70548057; called by mutect2, varscan2
- DCC | c.1805A>T p.N602I | Missense Mutation (SNP) | VAF 80/80 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59115942; called by muse, mutect2, varscan2
- DCHS1 | c.6869T>C p.L2290S | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55043155; called by muse, varscan2
- DDIAS | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs561618895; called by muse, varscan2
- DDX24 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 109/277 reads (39%) | catalogued as COSV100427973; called by muse, mutect2, varscan2
- DDX60 | c.1652C>T p.S551L | Missense Mutation (SNP) | VAF 190/192 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs761677522, COSV67096562; called by muse, mutect2, varscan2
- DDX60 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 246/247 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV67099548; called by muse, mutect2, varscan2
- DEFB115 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 226/278 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as rs755655392; called by muse, mutect2, varscan2
- DENND4C | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 132/132 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405706072; called by muse, mutect2, varscan2
- DLGAP3 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 217/649 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV52392177; called by muse, mutect2, varscan2
- DMRTA1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV100364867; called by muse, mutect2, varscan2
- DNAH10 | c.4676C>T p.S1559L (on ENST00000409039; = p.S1498L on NM_207437.3) | Missense Mutation (SNP) | VAF 146/146 reads (100%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as rs762069342; called by muse, mutect2, varscan2
- DNAH17 | c.11035C>T p.L3679F | Missense Mutation (SNP) | VAF 180/406 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780519831; called by muse, mutect2, varscan2
- DNAH17 | c.8059G>A p.E2687K | Missense Mutation (SNP) | VAF 260/551 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748291573; called by muse, mutect2, varscan2
- DNAH5 | c.11329G>A p.E3777K | Missense Mutation (SNP) | VAF 352/481 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201213490; called by muse, mutect2, varscan2
- DNAH5 | c.8627G>A p.R2876K | Missense Mutation (SNP) | VAF 83/402 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV54221519; called by muse, mutect2, varscan2
- DNAH5 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54223692; called by muse, mutect2, varscan2
- DNAH5 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as rs868197877; called by muse, mutect2, varscan2
- DNAH6 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 134/210 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs111548143, COSV52877008; called by muse, mutect2, varscan2
- DNAH7 | c.11419C>T p.Q3807* | Nonsense Mutation (SNP) | VAF 116/183 reads (63%) | catalogued as rs867446312, COSV100414139, COSV56761586, COSV56774674; called by muse, mutect2, varscan2
- DNAH7 | c.5657G>A p.R1886Q | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs13034775; called by muse, mutect2, varscan2
- DNAH8 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1296329386; called by muse, mutect2, varscan2
- DNAH8 | c.9406G>A p.E3136K | Missense Mutation (SNP) | VAF 105/340 reads (31%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.491); catalogued as COSV59434212; called by muse, mutect2, varscan2
- DNAH8 | c.12220C>T p.P4074S | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601021, COSV59448034; called by muse, mutect2, varscan2
- DNAI3 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 115/264 reads (44%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.539); catalogued as COSV54000327; called by muse, mutect2, varscan2
- DNAI3 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 115/264 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV54002387; called by muse, mutect2, varscan2
- DNAJC5B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 164/268 reads (61%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs141686243, COSV52535470; called by muse, varscan2
- DNASE1L3 | c.546G>A p.E182= | Splice Region (SNP) | VAF 134/238 reads (56%) | catalogued as rs1201586524; called by muse, mutect2, varscan2
- DNER | c.1403T>C p.L468P | Missense Mutation (SNP) | VAF 165/446 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV59160080; called by muse, mutect2, varscan2
- DNM3 | c.1714C>T p.P572S (on ENST00000355305 / NM_001350206.2; = p.P562S on NM_015569.5) | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs752381838; called by muse, mutect2, varscan2
- DNTTIP2 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 131/286 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs776402469; called by muse, mutect2, varscan2
- DOCK10 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 125/364 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1224011972; called by muse, mutect2, varscan2
- DOCK3 | c.2281C>T p.Q761* | Nonsense Mutation (SNP) | VAF 292/481 reads (61%) | catalogued as COSV99810460; called by muse, mutect2, varscan2
- DOCK3 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 250/398 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as rs1302203796; called by muse, varscan2
- DOCK3 | c.4207C>T p.P1403S | Missense Mutation (SNP) | VAF 137/459 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.044); catalogued as rs1422888538; called by muse, mutect2, varscan2
- DOCK4 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 296/556 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1421882969, COSV70234917; called by muse, mutect2, varscan2
- DOP1B | c.5804C>T p.P1935L | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101215050; called by muse, mutect2, varscan2
- DOT1L | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 313/781 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs781640234; called by muse, mutect2, varscan2
- DPP6 | c.253G>A p.G85R (on ENST00000377770 / NM_001364500.2; = p.G23R on NM_001936.5) | Missense Mutation (SNP) | VAF 102/237 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122333, COSV100127589; called by muse, mutect2, varscan2
- DSP | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 143/419 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1060500620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSTYK | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 293/654 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1423121390; called by muse, mutect2, varscan2
- DUSP11 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 82/151 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as rs1558534864; called by muse, mutect2, varscan2
- DYRK3 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 277/576 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1553420740; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 224/361 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779182481; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 279/431 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs772597833; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 209/397 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs1270644579; called by muse, mutect2, varscan2
- EEF1AKNMT | c.2016G>T p.L672F (on ENST00000361735 / NM_015935.5; = p.L586F on NM_014955.3) | Missense Mutation (SNP) | VAF 258/400 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100676049; called by muse, mutect2, varscan2
- EEF2K | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 341/341 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.4); catalogued as rs1219770042, COSV99532611; called by muse, mutect2, varscan2
- EFCAB8 | c.2821C>T p.P941S | Missense Mutation (SNP) | VAF 81/424 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.95); catalogued as rs1354026107; called by muse, varscan2
- EFHC1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64137649; called by muse, mutect2, varscan2
- EGFLAM | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 385/531 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1461002865, COSV100380490; called by muse, mutect2, varscan2
- EHD2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 201/552 reads (36%) | catalogued as COSV99621944; called by muse, mutect2, varscan2
- EHD3 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 136/341 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59031720; called by muse, mutect2, varscan2
- EIF4G3 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 124/201 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs950216111, COSV51690121; called by muse, mutect2, varscan2
- ELANE | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 200/568 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1555709342, COSV52256455; ClinVar: uncertain significance; called by muse, varscan2
- ELAPOR2 | c.2521C>T p.P841S (on ENST00000450689 / NM_001142749.3; = p.P674S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 200/424 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51884556; called by muse, mutect2, varscan2
- ELOA | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 67/267 reads (25%) | catalogued as rs1225403142; called by muse, mutect2, varscan2
- ELP3 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 240/472 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs749474343, COSV56459999; called by muse, mutect2, varscan2
- ELP4 | c.697C>T p.Q233* (on ENST00000350638; = p.Q232* on NM_019040.5) | Nonsense Mutation (SNP) | VAF 155/228 reads (68%) | catalogued as rs1357038410; called by muse, mutect2, varscan2
- EML3 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 276/439 reads (63%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs767044881; called by muse, mutect2, varscan2
- EML5 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 93/201 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs773834442, COSV61352259; called by muse, mutect2, varscan2
- ENPP4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 125/363 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV58088221, COSV58088735; called by muse, mutect2, varscan2
- ENTPD7 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 140/321 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748202130; called by muse, mutect2
- EPB41L4A | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs774150056, COSV99079267; called by muse, mutect2, varscan2
- EPHA2 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 384/802 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100626198; called by muse, mutect2, varscan2
- EPHA7 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1562049937; called by muse, mutect2, varscan2
- EPHB2 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 176/544 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1215107970; called by muse, mutect2, varscan2
- EPN2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59060580; called by muse, mutect2, varscan2
- EPYC | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 184/319 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754135032, COSV53798497; called by muse, mutect2, varscan2
- ERBB4 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 111/328 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0.06); catalogued as rs144842611, COSV61506927; called by muse, mutect2, varscan2
- ERC2 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 208/323 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs780698592, COSV55672206; called by muse, mutect2, varscan2
- ERICH3 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 227/430 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.168); catalogued as COSV58602480; called by muse, mutect2, varscan2
- ERICH6 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 299/301 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV55799220; called by muse, mutect2, varscan2
- ERN2 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs887550309; called by muse, mutect2, varscan2
- ERVFRD-1 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 202/285 reads (71%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as rs766557849, COSV65368584; called by muse, mutect2, varscan2
- ESPL1 | c.1934C>T p.T645I | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV57757367; called by muse, mutect2, varscan2
- ESR1 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 145/270 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52781079; called by muse, mutect2, varscan2
- ESR1 | c.1174G>C p.V392L | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV52782387; called by muse, mutect2, varscan2
- ETV6 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 201/286 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67150057, COSV67152262; called by muse, mutect2, varscan2
- EVPL | c.4645G>A p.A1549T | Missense Mutation (SNP) | VAF 464/963 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100044431; called by muse, mutect2, varscan2
- EVPL | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 371/763 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767324618, COSV56908538; called by muse, mutect2, varscan2
- EXD1 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as rs374507380; called by muse, mutect2, varscan2
- EXOC6B | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 147/373 reads (39%) | catalogued as rs369498012; called by muse, mutect2, varscan2
- EXPH5 | c.3376C>T p.P1126S | Missense Mutation (SNP) | VAF 280/280 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1442229862; called by muse, mutect2, varscan2
- EYS | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 97/206 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs907697038; called by muse, mutect2, varscan2
- FAM13C | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV53246271; called by muse, mutect2, varscan2
- FAM166C | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 256/643 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as rs1285725550, COSV61594074; called by muse, mutect2, varscan2
- FAM171A1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 209/323 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1454149720, COSV100968479; called by muse, mutect2, varscan2
- FAM189B | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 263/566 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs763340243; called by muse, mutect2, varscan2
- FAM214A | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 48/466 reads (10%) | catalogued as rs200373322, COSV55922249; called by muse, mutect2
- FAM221B | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 100/179 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs267602231, COSV100941219; called by muse, mutect2, varscan2
- FAM83H | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 278/795 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs1554624115; called by muse, mutect2, varscan2
- FARS2 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51165307; called by muse, mutect2, varscan2
- FAT4 | c.10031G>A p.R3344Q | Missense Mutation (SNP) | VAF 240/240 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs769028469, COSV58676528; called by muse, mutect2, varscan2
- FAT4 | c.13697C>T p.P4566L | Missense Mutation (SNP) | VAF 263/263 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV58674970; called by muse, mutect2, varscan2
- FBH1 | c.1142C>T p.T381I (on ENST00000362091 / NM_178150.3; = p.T432I on NM_032807.4) | Missense Mutation (SNP) | VAF 263/404 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1340597635; called by muse, mutect2, varscan2
- FBH1 | c.1220A>G p.Y407C (on ENST00000362091 / NM_178150.3; = p.Y458C on NM_032807.4) | Missense Mutation (SNP) | VAF 115/180 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs912547395; called by muse, mutect2, varscan2
- FBN1 | c.4352C>T p.S1451F | Missense Mutation (SNP) | VAF 28/393 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100354139; called by muse, mutect2
- FBN3 | c.5794G>A p.E1932K | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54456058; called by muse, mutect2, varscan2
- FBXO40 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 380/710 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV57527104; called by muse, mutect2, varscan2
- FCAMR | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 253/512 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); catalogued as rs865944502; called by muse, mutect2, varscan2
- FCGR1A | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 254/557 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1161084692, COSV100977284; called by muse, mutect2, varscan2
- FCRL3 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 168/272 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as rs746762170; called by muse, mutect2, varscan2
- FCRL6 | c.1180-1G>A p.X394_splice | Splice Site (SNP) | VAF 222/349 reads (64%) | catalogued as rs749199087; called by muse, mutect2
- FER1L6 | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 203/334 reads (61%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.8); catalogued as COSV67549766; called by muse, mutect2, varscan2
- FFAR1 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 187/509 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1272926150; called by muse, mutect2, varscan2
- FGF4 | c.343C>T p.L115= | Splice Region (SNP) | VAF 139/431 reads (32%) | catalogued as COSV51449277; called by muse, mutect2, varscan2
- FGFBP1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 227/227 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52587320; called by muse, mutect2, varscan2
- FGFR1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 324/760 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.261); catalogued as rs200116660; called by muse, mutect2, varscan2
- FGFR2 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 114/215 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs998662110, COSV60643939; called by muse, mutect2, varscan2
- FHL5 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58739365; called by muse, mutect2, varscan2
- FKBP15 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1418288662; called by muse, mutect2, varscan2
- FLG | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 143/334 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.367); catalogued as rs1228611224, COSV64242219; called by muse, mutect2, varscan2
- FLT1 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 135/595 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99164223; called by muse, mutect2, varscan2
- FLT1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 83/441 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV56728011; called by muse, mutect2, varscan2
- FMN2 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 148/390 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60420267; called by muse, mutect2, varscan2
- FMO3 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 202/330 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as rs1353702156, COSV63008662; called by muse, mutect2, varscan2
- FMR1NB | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 93/93 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV63272717; called by muse, mutect2, varscan2
- FNDC1 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51949627; called by muse, mutect2, varscan2
- FNDC1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 132/257 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs370527562; called by muse, mutect2, varscan2
- FNDC3B | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 321/638 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs762528973; called by muse, mutect2, varscan2
- FOLR1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 243/379 reads (64%) | SIFT tolerated (0.82); PolyPhen benign (0.038); catalogued as COSV56616329; called by muse, mutect2, varscan2
- FOXG1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 101/190 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57396312; called by muse, mutect2, varscan2
- FOXN1 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56883377; called by muse, mutect2, varscan2
- FPR3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 177/321 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs779072888, COSV59331000; called by muse, mutect2, varscan2
- FREM2 | c.5293C>T p.R1765C | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs770772406, COSV54826790; called by muse, mutect2, varscan2
- FREM2 | c.6157C>T p.P2053S | Missense Mutation (SNP) | VAF 267/346 reads (77%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as rs767742573; called by muse, mutect2, varscan2
- FRMD3 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 137/337 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV58472547; called by muse, mutect2, varscan2
- FTCD | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754562126; called by muse, mutect2, varscan2
- FTCD | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 158/340 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs775567630; called by muse, mutect2, varscan2
- FUT3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 207/824 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV99744937; called by muse, varscan2
- FUT8 | c.1322G>A p.R441Q (on ENST00000360689 / NM_001371534.1; = p.R278Q on NM_004480.4) | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs758856033, COSV61290251; called by muse, mutect2, varscan2
- FYB2 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs749801475; called by muse, mutect2, varscan2
- FZD7 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 203/504 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV53808730; called by muse, mutect2, varscan2
- G3BP2 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV62975713; called by muse, mutect2, varscan2
- GAB3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 242/243 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65818942, COSV65820626; called by muse, mutect2, varscan2
- GABRB2 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs150956270, COSV50906276; called by muse, mutect2, varscan2
- GALNT14 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 239/392 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs373408955; called by muse, mutect2, varscan2
- GALNT17 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 145/333 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773651456, COSV61160937; called by muse, mutect2, varscan2
- GAPVD1 | c.2780G>A p.R927Q (on ENST00000394104; = p.R954Q on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/263 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs1190889306; called by muse, mutect2, varscan2
- GET3 | c.619A>C p.M207L | Missense Mutation (SNP) | VAF 158/410 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV100628239; called by muse, mutect2, varscan2
- GIMAP4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 144/377 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV55434967; called by muse, mutect2, varscan2
- GIMAP8 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 194/497 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1165066384, COSV56230314; called by muse, mutect2, varscan2
- GLB1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 45/1686 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867088810; called by muse, mutect2
- GLRA2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 183/183 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.131); catalogued as COSV54344147; called by muse, mutect2, varscan2
- GLYATL1 | c.291G>A p.W97* (on ENST00000317391 / NM_001354699.1; = p.W128* on NM_080661.4) | Nonsense Mutation (SNP) | VAF 76/195 reads (39%) | catalogued as rs1297270806; called by muse, mutect2, varscan2
- GLYATL3 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as rs1018824721, COSV100966325; called by muse, mutect2, varscan2
- GNAL | c.618C>T p.F206= (on ENST00000269162 / NM_001142339.3; = p.F283= on NM_182978.4) | Splice Region (SNP) | VAF 73/160 reads (46%) | catalogued as COSV52326254, COSV99304042; called by muse, mutect2, varscan2
- GNAS | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 176/743 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1302332433, COSV58333722; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 409/1004 reads (41%) | SIFT deleterious, low confidence (0.01); catalogued as rs1295580440; called by muse, mutect2, varscan2
- GOLGA6L2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.428); catalogued as rs774878575, COSV61478240; called by muse, mutect2, varscan2
- GPA33 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 140/293 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV63302188; called by muse, mutect2, varscan2
- GPAT2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 108/396 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64003173; called by muse, mutect2, varscan2
- GPN1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 167/479 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1415858850, COSV53114795; called by muse, mutect2, varscan2
- GPR161 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 261/569 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775719346, COSV54790780; called by muse, mutect2, varscan2
- GPR45 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 285/486 reads (59%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51523913; called by muse, mutect2, varscan2
- GPRIN1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 149/360 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.164); catalogued as rs549297346, COSV56136594; called by muse, mutect2, varscan2
- GPRIN2 | c.717_718insAAGATGAGG p.R239_E240insKMR | In Frame Ins (INS) | VAF 84/190 reads (44%) | catalogued as rs1345854053; called by mutect2, varscan2
- GRHL2 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 128/350 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52549020; called by muse, mutect2, varscan2
- GRHPR | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 113/222 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs764111479, COSV58944536; called by muse, varscan2
- GRIA2 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs201867927, COSV52396761; called by muse, mutect2, varscan2
- GRIN1 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV59293333; called by muse, mutect2, varscan2
- GRIN2A | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1555481892, COSV58025645; called by muse, mutect2, varscan2
- GRIN3A | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 152/517 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); catalogued as rs112914306; called by muse, mutect2, varscan2
- GRM8 | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 169/382 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58825161; called by muse, mutect2, varscan2
- GRWD1 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 171/372 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs771758365; called by muse, mutect2, varscan2
- GTF2E1 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 307/604 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV52206473, COSV99382067; called by muse, mutect2, varscan2
- GUCA1C | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 229/361 reads (63%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as rs1215597864, COSV53755071; called by muse, mutect2, varscan2
- H2AC1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 121/484 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV51236684; called by muse, mutect2, varscan2
- H2BC8 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1561989055; called by muse, mutect2, varscan2
- HABP2 | c.1647G>A p.W549* | Nonsense Mutation (SNP) | VAF 129/257 reads (50%) | catalogued as COSV63491040; called by muse, varscan2
- HCRTR2 | c.1156G>C p.V386L | Missense Mutation (SNP) | VAF 123/367 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs375477231; called by muse, mutect2, varscan2
- HDC | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs867414908, COSV51081078; called by muse, mutect2
- HEATR1 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63983008; called by muse, mutect2, varscan2
- HERC1 | c.7310C>T p.A2437V | Missense Mutation (SNP) | VAF 185/378 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs775464349; called by muse, mutect2, varscan2
- HEYL | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 174/385 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV65721530; called by muse, mutect2, varscan2
- HEYL | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 175/388 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV65722116; called by muse, mutect2, varscan2
- HIVEP3 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 346/657 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.219); catalogued as rs1213224750; called by muse, mutect2, varscan2
- HMGCLL1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.646); catalogued as rs772259012, COSV51441906; called by muse, mutect2, varscan2
- HOXB1 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 294/546 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879025404; called by muse, mutect2, varscan2
- HRG | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 192/436 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs886729944; called by muse, mutect2, varscan2
- HRNR | c.6479G>A p.G2160D | Missense Mutation (SNP) | VAF 201/6394 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1284825410, COSV64260163; called by muse, mutect2
- HRNR | c.5837C>T p.S1946F | Missense Mutation (SNP) | VAF 222/6328 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV100913577; called by muse, mutect2
- HRNR | c.5069G>A p.G1690D | Missense Mutation (SNP) | VAF 150/2522 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1329445728; called by muse, mutect2
- HSD17B13 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 171/171 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs747544810; called by muse, mutect2, varscan2
- HTR1A | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 135/388 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs1273554893; called by muse, mutect2, varscan2
- HTR1A | c.646G>T p.G216W | Missense Mutation (SNP) | VAF 133/380 reads (35%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.824); catalogued as COSV60502398; called by muse, mutect2, varscan2
- HTR4 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 114/197 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as rs1215993084, COSV58791571; called by muse, mutect2, varscan2
- IFIH1 | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 206/402 reads (51%) | catalogued as rs750804689, COSV55125658; ClinVar: uncertain significance; called by muse, mutect2
- IFNL2 | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 221/363 reads (61%) | catalogued as rs772249678; called by muse, mutect2, varscan2
- IGF1R | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 83/386 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1198959559, COSV51277320; called by muse, mutect2, varscan2
- IGHG4 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 154/464 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779939638; called by muse, mutect2, varscan2
- IGHV1-46 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 119/263 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs531889359; called by muse, mutect2, varscan2
- IGHV2-70 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs568088145; called by muse, mutect2, varscan2
- IGHV3-16 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 117/237 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs782709611; called by muse, mutect2, varscan2
- IGLV6-57 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 170/303 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.988); catalogued as rs1417851932; called by muse, mutect2, varscan2
- IGLV8-61 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 244/396 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs542479842, COSV66502625; called by muse, mutect2, varscan2
- IGSF21 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 201/425 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.04); catalogued as rs767393509; called by muse, mutect2, varscan2
- IKBKE | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 271/586 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65626620; called by muse, mutect2, varscan2
- IL18RAP | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 107/321 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as rs142509174; called by muse, mutect2, varscan2
- IL1RL2 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 121/301 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV51816466; called by muse, mutect2, varscan2
- IL20RA | c.222C>T p.F74= | Splice Region (SNP) | VAF 72/135 reads (53%) | catalogued as COSV57361110; called by muse, mutect2, varscan2
- IL7R | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 145/680 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV57409966; called by muse, mutect2, varscan2
- INPP5A | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 105/207 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61248333; called by muse, mutect2, varscan2
- INPP5B | c.2072C>T p.S691F (on ENST00000373023; = p.S611F on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 119/309 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV65962864; called by muse, mutect2, varscan2
- INSR | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 137/367 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57169947; called by muse, mutect2, varscan2
- INTS6 | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 359/450 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60879022; called by muse, mutect2, varscan2
- IP6K2 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 173/555 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1301547341; called by muse, mutect2, varscan2
- IQCA1L | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 214/538 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs946252876, COSV51999331; called by muse, mutect2, varscan2
- IQCN | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 218/642 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs146596461; called by muse, mutect2, varscan2
- IQCN | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 218/643 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV66573577; called by muse, mutect2, varscan2
- IQSEC3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 197/1024 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs781892955; called by muse, mutect2, varscan2
- IRAK2 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 163/471 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56528581; called by muse, mutect2, varscan2
- IRGC | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 238/642 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.289); catalogued as rs778870905; called by muse, mutect2
- ISLR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 308/651 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs868123537, COSV99997227; called by muse, mutect2, varscan2
- ITGA1 | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV50901044; called by muse, mutect2, varscan2
- ITGA11 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 311/643 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs544682550; called by muse, mutect2, varscan2
- ITGA11 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 149/670 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1325429944; called by muse, mutect2
- ITIH5 | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 227/340 reads (67%) | SIFT tolerated (0.81); PolyPhen benign (0.031); catalogued as rs369347222; called by muse, mutect2, varscan2
- ITLN1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 307/644 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs372878387; called by muse, mutect2, varscan2
- IVL | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 330/705 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1220421012; called by muse, mutect2, varscan2
- JMY | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 88/279 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs772805107, COSV68662815; called by muse, mutect2, varscan2
- KANSL1L | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762505094, COSV55993885; called by muse, mutect2, varscan2
- KAT6B | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 160/339 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1054836015; called by muse, mutect2, varscan2
- KBTBD12 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 95/95 reads (100%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as COSV100675495; called by muse, mutect2, varscan2
- KBTBD12 | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 142/143 reads (99%) | catalogued as COSV59681272; called by muse, mutect2, varscan2
- KCNA6 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 317/472 reads (67%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs866418364, COSV54974491; called by muse, mutect2, varscan2
- KCND3 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 209/482 reads (43%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.062); catalogued as rs764928165, COSV56188774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ5 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 353/353 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148462487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK18 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 174/516 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV57973296; called by muse, mutect2, varscan2
- KCNK5 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 154/516 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.022); catalogued as COSV100851864; called by muse, mutect2, varscan2
- KCNU1 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 192/318 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101299116; called by muse, mutect2, varscan2
- KCTD16 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 218/334 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769455523; called by muse, mutect2, varscan2
- KHDRBS2 | c.869del p.N290Tfs*20 | Frame Shift Del (DEL) | VAF 93/244 reads (38%) | catalogued as COSV99838937; called by mutect2, pindel, varscan2
- KIAA0319 | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 70/305 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs866430826; called by muse, mutect2
- KIAA1210 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 142/142 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV68177424; called by muse, mutect2, varscan2
- KIAA1614 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 166/520 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs200156750, COSV100851235, COSV62550572; called by muse, mutect2, varscan2
- KIF18B | c.2042C>T p.S681F (on ENST00000593135 / NM_001265577.2; = p.S693F on NM_001264573.2) | Missense Mutation (SNP) | VAF 238/569 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs371854103; called by muse, mutect2, varscan2
- KIF18B | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV59275034; called by muse, mutect2, varscan2
- KIF26B | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 439/871 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs763980355; called by muse, mutect2, varscan2
- KIF2B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 198/488 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs1229299890, COSV52127464; called by muse, mutect2, varscan2
- KIF5A | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV54056649; called by muse, mutect2, varscan2
- KIF6 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.421); catalogued as COSV54674181, COSV54684039; called by muse, mutect2, varscan2
- KL | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 188/903 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1386106688; called by muse, mutect2, varscan2
- KL | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 125/714 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779841444, COSV104430440; called by muse, mutect2, varscan2
- KLHL14 | c.1056G>A p.W352* | Nonsense Mutation (SNP) | VAF 170/171 reads (99%) | catalogued as COSV63834569; called by muse, mutect2, varscan2
- KMT2C | c.5396C>T p.S1799L | Missense Mutation (SNP) | VAF 242/413 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV51425929; called by muse, mutect2, varscan2
- KMT2C | c.1072T>A p.F358I | Missense Mutation (SNP) | VAF 96/526 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV51430903; called by muse, varscan2
- KNTC1 | c.4495C>T p.L1499F | Missense Mutation (SNP) | VAF 301/302 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs772694843, COSV61083809; called by muse, mutect2, varscan2
- KRT10 | c.1408G>A p.G470S | Missense Mutation (SNP) | VAF 318/551 reads (58%) | SIFT tolerated (0.99); PolyPhen benign (0.339); catalogued as rs1334942148; called by muse, mutect2, varscan2
- KRT15 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 112/248 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs1423698306, COSV54180898; called by muse, mutect2, varscan2
- KRT23 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 158/303 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.145); catalogued as rs897151182, COSV52926966, COSV52927053; called by muse, mutect2, varscan2
- KRT24 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 178/288 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs749502511; called by muse, mutect2, varscan2
- KRT24 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 275/446 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1309519674; called by muse, mutect2, varscan2
- KRT25 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 230/541 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs754517768, COSV100380021, COSV56444403; called by muse, mutect2, varscan2
- KRT28 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 314/596 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV100137789; called by muse, mutect2, varscan2
- KRT33B | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 218/547 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as rs759598244; called by muse, mutect2, varscan2
- KRTAP10-11 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 205/481 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs199741257; called by muse, mutect2, varscan2
- KRTAP4-6 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 489/942 reads (52%) | SIFT deleterious (0); catalogued as COSV100624081; called by muse, mutect2, varscan2
- L3MBTL1 | c.1601G>A p.R534Q (on ENST00000418998 / NM_001377303.1; = p.R444Q on NM_015478.7) | Missense Mutation (SNP) | VAF 201/282 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756904545, COSV64228025; called by muse, mutect2, varscan2
- LAMA5 | c.5137C>T p.R1713C | Missense Mutation (SNP) | VAF 108/510 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs374046052; called by muse, mutect2, varscan2
- LAMB1 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 307/616 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as rs777314468, COSV55963235; called by muse, mutect2, varscan2
- LAMB3 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 210/478 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV61915717; called by muse, mutect2, varscan2
- LAMB4 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 355/776 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs770761096; called by muse, mutect2, varscan2
- LAMC2 | c.2747G>A p.G916E | Missense Mutation (SNP) | VAF 157/252 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777067409, COSV51454380; called by muse, mutect2
- LAMC3 | c.4256G>A p.R1419Q | Missense Mutation (SNP) | VAF 131/270 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs201597071, COSV62653934; called by muse, mutect2, varscan2
- LBP | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 324/450 reads (72%) | SIFT tolerated (0.79); PolyPhen benign (0.194); catalogued as rs757338505; called by muse, mutect2, varscan2
- LCA5L | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 111/197 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs555546608, COSV55744077; called by muse, mutect2, varscan2
- LCE1F | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 329/690 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs1329567979, COSV57668676; called by muse, mutect2, varscan2
- LCK | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 308/495 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs759646706, COSV60739481; called by muse, mutect2, varscan2
- LCNL1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 203/384 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs375042346; called by muse, mutect2, varscan2
- LDLR | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 174/484 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.073); catalogued as rs1368762538; called by muse, mutect2, varscan2
- LEXM | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 271/544 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200886761, COSV64024196; called by muse, mutect2, varscan2
- LILRA2 | c.1360G>A p.G454S (on ENST00000391738 / NM_001130917.3; = p.G437S on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 293/674 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV99253784; called by muse, mutect2, varscan2
- LILRB5 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 127/282 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV60254414; called by muse, mutect2, varscan2
- LIMCH1 | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58287195; called by muse, mutect2, varscan2
- LPCAT4 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 82/373 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs564033666; called by muse, mutect2, varscan2
- LPIN1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 156/422 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs185471985, COSV56763136; called by muse, mutect2, varscan2
- LRFN5 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53279447; called by muse, mutect2, varscan2
- LRP12 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 265/426 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV52628890; called by muse, mutect2, varscan2
- LRP1B | c.12596G>A p.G4199E | Missense Mutation (SNP) | VAF 199/330 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs868543953, COSV67186838; called by muse, mutect2, varscan2
- LRP1B | c.9967C>T p.R3323C | Missense Mutation (SNP) | VAF 103/197 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1328117748, COSV67187455; called by muse, mutect2, varscan2
- LRP1B | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 171/380 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67213531; called by muse, mutect2, varscan2
- LRP1B | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV67226319; called by muse, mutect2, varscan2
- LRP2 | c.11206C>T p.R3736C | Missense Mutation (SNP) | VAF 145/351 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275575465, COSV55544664; called by muse, mutect2, varscan2
- LRP4 | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 123/358 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs768053076, COSV66135741; called by muse, mutect2, varscan2
- LRRC2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs758828256, COSV56126105, COSV99947331; called by muse, mutect2, varscan2
- LRRC34 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 106/251 reads (42%) | catalogued as rs1170217067; called by muse, mutect2, varscan2
- LRRC4C | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 223/346 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs773078198, COSV53433740; called by muse, mutect2, varscan2
- LRRC70 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 118/324 reads (36%) | catalogued as rs752188484; called by muse, mutect2, varscan2
- LRRN1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 128/422 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267599792, COSV60013540; called by muse, mutect2, varscan2
- LRRTM1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 198/571 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as rs570950310, COSV54446546; called by muse, mutect2, varscan2
- LRRTM4 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 252/431 reads (58%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.06); catalogued as COSV69153795; called by muse, varscan2
- LSMEM2 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 187/297 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV57113124; called by muse, mutect2, varscan2
- MAG | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 223/596 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV100728047; called by muse, mutect2, varscan2
- MAGEA1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 186/187 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63118372; called by muse, mutect2, varscan2
- MAGEB5 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 385/385 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66869265; called by muse, mutect2, varscan2
- MAGEC1 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 221/223 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99596422; called by muse, mutect2, varscan2
- MAGEL2 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 79/382 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV100045767; called by muse, mutect2, varscan2
- MAN2A1 | c.2941C>T p.R981* | Nonsense Mutation (SNP) | VAF 96/150 reads (64%) | catalogued as rs761015143, COSV54846814; called by muse, mutect2, varscan2
- MAN2B1 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 194/463 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1289169338, COSV54419097; called by muse, mutect2, varscan2
- MAP3K6 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 309/514 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs146598623; called by muse, mutect2, varscan2
- MAP7D1 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 120/365 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs759769970; called by mutect2, varscan2
- MAPK11 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 237/381 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53135526; called by muse, mutect2, varscan2
- MARCHF10 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 233/438 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs1375164901; called by muse, mutect2, varscan2
- MARCO | c.1090G>C p.G364R | Missense Mutation (SNP) | VAF 122/241 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59057052; called by muse, mutect2, varscan2
- MBD5 | c.3251C>T p.S1084F | Missense Mutation (SNP) | VAF 167/284 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV101290277; called by muse, mutect2, varscan2
- MCF2L2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 208/432 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61061298; called by muse, varscan2
- MCM3 | c.209C>T p.S70F (on ENST00000229854 / NM_001366374.2; = p.F22= on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.471); catalogued as rs1487344814; called by muse, varscan2
- MCPH1 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 198/374 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769776443, COSV60911222; called by muse, mutect2, varscan2
- MCUB | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 273/274 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54460263; called by muse, mutect2, varscan2
- MDM1 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 128/128 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as COSV57448632; called by muse, mutect2, varscan2
- MECOM | c.922C>T p.P308S (on ENST00000468789 / NM_001105078.4; = p.P496S on NM_004991.4) | Missense Mutation (SNP) | VAF 256/529 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV52959050; called by muse, mutect2, varscan2
- MED25 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 163/296 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs1001322913, COSV57207305; called by muse, mutect2, varscan2
- MEF2D | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 320/742 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1305911253; called by muse, mutect2, varscan2
- MEI1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 205/362 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV55903106; called by muse, mutect2, varscan2
- METTL11B | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 237/369 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV63029953, COSV63030280; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 196/389 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, mutect2, varscan2
- MGAM | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 224/816 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866544940, COSV72074972; called by muse, mutect2, varscan2
- MIA3 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 244/405 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60513444; called by muse, mutect2, varscan2
- MITD1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 119/326 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202212055; called by muse, mutect2, varscan2
- MNS1 | c.126G>C p.M42I | Missense Mutation (SNP) | VAF 60/443 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53068505; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1927C>T p.L643F | Missense Mutation (SNP) | VAF 117/117 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56617077; called by muse, mutect2, varscan2
- MROH2A | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs967875828; called by muse, mutect2, varscan2
- MROH5 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 256/349 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs371347936; called by muse, varscan2
- MROH7 | c.3638C>T p.S1213F | Missense Mutation (SNP) | VAF 220/476 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as rs1373000656, COSV64887248; called by muse, mutect2, varscan2
- MROH9 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752447106; called by muse, mutect2, varscan2
- MRPL19 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 102/182 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs947209529, COSV62566478; called by muse, mutect2, varscan2
- MTBP | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 137/235 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs1177215121, COSV59960765; called by muse, mutect2, varscan2
- MTNR1A | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 292/293 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1245979910; called by muse, mutect2, varscan2
- MTNR1B | c.757A>G p.M253V | Missense Mutation (SNP) | VAF 255/558 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as rs1373695611; called by muse, mutect2, varscan2
- MTNR1B | c.758T>C p.M253T | Missense Mutation (SNP) | VAF 252/558 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as rs748867223, COSV99925121; called by muse, mutect2, varscan2
- MTOR | c.5431C>T p.R1811C | Missense Mutation (SNP) | VAF 365/677 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1258909652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTUS2 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 413/544 reads (76%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV70922428; called by muse, mutect2, varscan2
- MUC12 | c.13123C>T p.P4375S (on ENST00000379442; = p.P4232S on NM_001164462.1) | Missense Mutation (SNP) | VAF 396/1550 reads (26%) | SIFT deleterious (0.05); catalogued as rs778933247; called by muse, mutect2, varscan2
- MUC16 | c.41599G>A p.D13867N | Missense Mutation (SNP) | VAF 165/452 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.968); catalogued as rs1296301073; called by muse, mutect2, varscan2
- MUC16 | c.38048G>A p.G12683E | Missense Mutation (SNP) | VAF 125/194 reads (64%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs751445901; called by muse, mutect2, varscan2
- MUC16 | c.37810G>A p.E12604K | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs749277251, COSV101197836, COSV67466588; called by muse, mutect2, varscan2
- MUC16 | c.31199G>A p.R10400K | Missense Mutation (SNP) | VAF 238/402 reads (59%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.1); catalogued as COSV67464408; called by muse, mutect2, varscan2
- MUC16 | c.28573A>T p.T9525S | Missense Mutation (SNP) | VAF 186/501 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.556); catalogued as rs1270105082; called by muse, mutect2, varscan2
- MUC16 | c.23413G>A p.D7805N | Missense Mutation (SNP) | VAF 157/437 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.184); catalogued as rs761251311, COSV67488271; called by muse, mutect2, varscan2
- MUC16 | c.15701C>T p.S5234F | Missense Mutation (SNP) | VAF 153/387 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV67445111; called by muse, mutect2, varscan2
- MUC16 | c.7991C>T p.S2664F | Missense Mutation (SNP) | VAF 164/386 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67477336; called by muse, mutect2, varscan2
- MUC16 | c.7114G>A p.D2372N | Missense Mutation (SNP) | VAF 118/221 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs867466995, COSV67460769; called by muse, mutect2, varscan2
- MUC17 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 296/766 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs139093882, COSV60299425; called by muse, mutect2, varscan2
- MUC17 | c.6653G>A p.G2218E | Missense Mutation (SNP) | VAF 373/727 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1474855225; called by muse, mutect2, varscan2
- MUC3A | c.7532C>T p.S2511F | Missense Mutation (SNP) | VAF 286/607 reads (47%) | SIFT tolerated, low confidence (0.08); catalogued as rs541628829, COSV100114521, COSV100115421; called by muse, mutect2, varscan2
- MUC4 | c.13728G>A p.W4576* (on ENST00000463781 / NM_018406.7; = p.W340* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 554/1097 reads (51%) | catalogued as COSV57773311; called by muse, mutect2, varscan2
- MX1 | c.1813C>T p.L605F | Missense Mutation (SNP) | VAF 143/335 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1569001852; called by muse, mutect2, varscan2
- MYF5 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 126/325 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1381547702; called by muse, mutect2, varscan2
- MYF6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 118/180 reads (66%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs781756867, COSV99952722; called by muse, varscan2
- MYH1 | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99875976; called by muse, mutect2, varscan2
- MYH13 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 122/149 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756858193; called by muse, mutect2, varscan2
- MYH15 | c.3432G>A p.M1144I | Missense Mutation (SNP) | VAF 95/353 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs747627053; called by muse, mutect2, varscan2
- MYH4 | c.1554G>A p.M518I | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs558519475; called by muse, mutect2, varscan2
- MYH6 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV62449803; called by muse, mutect2
- MYH9 | c.5675C>T p.S1892F | Missense Mutation (SNP) | VAF 264/675 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as rs1450702017; called by muse, mutect2, varscan2
- MYLK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 258/570 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs564792567, COSV60604501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 366/368 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs981927941, COSV52756314; called by muse, mutect2, varscan2
- MYO16 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 90/446 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs776925771, COSV51803396; called by muse, mutect2, varscan2
- MYO18B | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 239/426 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs749666378, COSV59130355, COSV59131815; called by muse, mutect2, varscan2
- MYO18B | c.5881G>A p.D1961N | Missense Mutation (SNP) | VAF 236/394 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as COSV59144909; called by muse, varscan2
- MYO18B | c.6323G>A p.R2108Q | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs761193684, COSV59142649; called by muse, mutect2, varscan2
- MYO5C | c.898C>T p.R300* | Nonsense Mutation (SNP) | VAF 256/483 reads (53%) | catalogued as rs1241157229, COSV55909254; called by muse, mutect2, varscan2
- MYO6 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 50/128 reads (39%) | catalogued as rs369889326; called by muse, mutect2, varscan2
- MYO7B | c.5780C>T p.S1927L | Missense Mutation (SNP) | VAF 231/418 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs754903067, COSV61441918; called by muse, mutect2, varscan2
- MYOCD | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 307/307 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58514224; called by muse, mutect2, varscan2
- MYOM2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 169/452 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs148337899; called by muse, mutect2, varscan2
- NAALAD2 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 137/294 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV58960082; called by muse, mutect2, varscan2
- NAT10 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 109/371 reads (29%) | catalogued as rs765183435; called by muse, mutect2, varscan2
- NAV2 | c.2488C>T p.R830* (on ENST00000396087 / NM_001244963.2; = p.R807* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 176/509 reads (35%) | catalogued as rs865835391, COSV62319361; called by muse, mutect2, varscan2
- NBEAL1 | c.5857C>A p.L1953I | Missense Mutation (SNP) | VAF 142/270 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV68916340; called by muse, mutect2, varscan2
- NBR1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57835542; called by muse, mutect2, varscan2
- NCKAP5 | c.1598G>A p.R533K | Missense Mutation (SNP) | VAF 136/406 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs755256419; called by muse, mutect2, varscan2
- NCOA1 | c.3727G>A p.A1243T | Missense Mutation (SNP) | VAF 104/309 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1435683283, COSV99946009; called by muse, mutect2, varscan2
- NCOA2 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV71763953; called by muse, mutect2, varscan2
- NCR1 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 302/543 reads (56%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52557836; called by muse, mutect2, varscan2
- NCR1 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 365/731 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV52556814; called by muse, mutect2, varscan2
- NCR1 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 364/728 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as rs774857066, COSV52557516; called by muse, mutect2, varscan2
- NDST3 | c.2222G>A p.R741K | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1293181568; called by muse, mutect2, varscan2
- NEB | c.13879G>A p.D4627N | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs377429434; called by muse, mutect2, varscan2
- NEB | c.5615C>T p.P1872L | Missense Mutation (SNP) | VAF 241/430 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs760925535, COSV51121097; called by muse, mutect2, varscan2
- NEB | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 200/335 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs377599060; called by muse, mutect2, varscan2
- NEBL | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 104/355 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746529858, COSV101009015, COSV65802861; called by muse, mutect2, varscan2
- NEBL | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs768161805, COSV65802571; called by muse, mutect2, varscan2
- NEFH | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 254/467 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV100151669; called by muse, mutect2, varscan2
- NEMP2 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199878689, COSV58110018; called by mutect2, varscan2
- NES | c.3920C>T p.S1307F | Missense Mutation (SNP) | VAF 384/819 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV63960804; called by muse, mutect2, varscan2
- NEUROD1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 162/410 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs1349732855; called by muse, mutect2, varscan2
- NEXMIF | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV50041754, COSV50045392; called by muse, mutect2, varscan2
- NHSL2 | c.1622G>T p.R541M (on ENST00000510661; = p.R907M on NM_001013627.2) | Missense Mutation (SNP) | VAF 107/109 reads (98%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV101029995; called by muse, mutect2, varscan2
- NIBAN3 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 247/473 reads (52%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as rs1210760308; called by muse, mutect2, varscan2
- NID2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 134/268 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1468289403, COSV53495868; called by muse, mutect2
- NID2 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 123/229 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.313); catalogued as COSV53503403; called by muse, varscan2
- NID2 | c.2150C>T p.S717F | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV53497417, COSV99356589; called by muse, varscan2
- NIPSNAP2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 209/438 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59050621; called by muse, mutect2, varscan2
- NLN | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768326002; called by muse, mutect2, varscan2
- NLRP3 | c.2767G>A p.G923R | Missense Mutation (SNP) | VAF 248/506 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs767011471, COSV60220242, COSV60225995; called by muse, mutect2, varscan2
- NLRP4 | c.1414C>T p.H472Y | Missense Mutation (SNP) | VAF 248/510 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56713597; called by muse, mutect2
- NLRP4 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.948); catalogued as COSV56724524; called by muse, mutect2, varscan2
- NLRP8 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 151/385 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs866751626, COSV99405586; called by muse, mutect2, varscan2
- NLRP9 | c.524G>A p.W175* | Nonsense Mutation (SNP) | VAF 209/487 reads (43%) | catalogued as rs1466339921, COSV100242410, COSV100243693; called by muse, mutect2, varscan2
- NME1-NME2 | c.604C>T p.P202S (on ENST00000555572; = p.P177S on NM_001018136.3) | Missense Mutation (SNP) | VAF 214/372 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.144); catalogued as rs1297017824; called by muse, mutect2, varscan2
- NME8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 130/259 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs369542497; called by muse, mutect2, varscan2
- NOTCH3 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 387/600 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475080033, CM003015; called by muse, mutect2, varscan2
- NOX5 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 265/607 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs776336697; called by muse, mutect2, varscan2
- NOX5 | c.1914G>A p.W638* | Nonsense Mutation (SNP) | VAF 90/365 reads (25%) | catalogued as rs1390603839; called by muse, mutect2, varscan2
- NPAP1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 265/343 reads (77%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs865895928, COSV61506356; called by muse, mutect2, varscan2
- NPHP4 | c.3754C>A p.L1252I | Missense Mutation (SNP) | VAF 341/692 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs398124290, COSV65392904; called by muse, mutect2, varscan2
- NPHS1 | c.3551C>T p.P1184L | Missense Mutation (SNP) | VAF 136/309 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1010795962; called by muse, mutect2, varscan2
- NPR1 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 173/370 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV64117958; called by muse, mutect2, varscan2
- NPR2 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 129/286 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as rs778410447, COSV100709796; called by muse, mutect2, varscan2
- NRXN2 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 172/552 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55459527; called by muse, mutect2, varscan2
- NSUN6 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 169/264 reads (64%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs867410434, COSV66031726; called by muse, mutect2, varscan2
- NT5DC4 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 199/537 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs551167032; called by muse, mutect2, varscan2
- NUAK1 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 166/537 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs186215853; called by muse, mutect2, varscan2
- NUAK1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 226/375 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772183684, COSV54605730; called by muse, mutect2, varscan2
- NUSAP1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as rs775051382, COSV52971848; called by muse, mutect2, varscan2
- NYAP2 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 134/218 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56015512; called by muse, mutect2, varscan2
- NYNRIN | c.3390G>A p.W1130* | Nonsense Mutation (SNP) | VAF 171/346 reads (49%) | catalogued as COSV66841090; called by muse, mutect2, varscan2
- OCM2 | c.63C>T p.D21= | Splice Region (SNP) | VAF 169/349 reads (48%) | catalogued as rs1354864552; called by muse, mutect2, varscan2
- OR10A5 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 124/390 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs867881604; called by muse, mutect2, varscan2
- OR10H2 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1055546295, COSV100008615; called by muse, mutect2, varscan2
- OR10H4 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 210/382 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs868676405; called by muse, mutect2, varscan2
- OR10J1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373330432, COSV101419901, COSV71128120; called by muse, mutect2, varscan2
- OR10J3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 170/488 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs867791135, COSV59953822; called by muse, varscan2
- OR10J3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 250/396 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59954348; called by muse, varscan2
- OR10Z1 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1557913278; called by muse, mutect2
- OR11H6 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.228); catalogued as rs866042152, COSV59645560; called by muse, mutect2, varscan2
- OR13C8 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 170/481 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV58610625; called by muse, mutect2, varscan2
- OR13C8 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 217/329 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58612259; called by muse, mutect2, varscan2
- OR13G1 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 207/432 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62943959; called by muse, mutect2, varscan2
- OR13H1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088332; called by muse, mutect2, varscan2
- OR2A2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 214/374 reads (57%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68872002; called by muse, mutect2, varscan2
- OR2F1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 162/304 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101231319, COSV67330780, COSV67332271; called by muse, mutect2, varscan2
- OR2G6 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 227/460 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58574474; called by muse, mutect2, varscan2
- OR2M5 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 249/576 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV63546261; called by muse, mutect2, varscan2
- OR2V1 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 183/320 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs748791857; called by muse, mutect2, varscan2
- OR4K5 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 95/208 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV60002682; called by muse, mutect2, varscan2
- OR4N5 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 124/280 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1329156063; called by muse, mutect2, varscan2
- OR4Q2 | c.525+1G>A | Missense Mutation (SNP) | VAF 121/281 reads (43%) | catalogued as rs895174410; called by muse, mutect2
- OR51B5 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 110/357 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1435926857, COSV56175601; called by muse, mutect2, varscan2
- OR51G1 | c.957G>A p.W319* | Nonsense Mutation (SNP) | VAF 79/231 reads (34%) | catalogued as rs769264009; called by muse, mutect2, varscan2
- OR51I1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 149/384 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100970755, COSV100971807; called by muse, mutect2, varscan2
- OR51L1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 132/373 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1212251668, COSV58624046; called by muse, mutect2, varscan2
- OR52E8 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 256/404 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV66204679; called by muse, varscan2
- OR52L1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 202/299 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs756450029; called by muse, mutect2, varscan2
- OR52N1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 237/356 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100398643; called by muse, mutect2, varscan2
- OR52W1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 157/426 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as rs780486061; called by muse, mutect2, varscan2
- OR56A3 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 319/439 reads (73%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV61569057; called by muse, mutect2, varscan2
- OR56B1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100402664; called by muse, mutect2, varscan2
- OR5A1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 156/467 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57377354; called by muse, mutect2, varscan2
- OR5AC2 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 311/443 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV62279154; called by muse, mutect2, varscan2
- OR5K1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 157/229 reads (69%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100221052, COSV60304383; called by muse, mutect2, varscan2
- OR5L1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 230/233 reads (99%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs149863919, COSV61733695; called by muse, mutect2, varscan2
- OR6Y1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 101/337 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV56928014, COSV56930171; called by muse, mutect2, varscan2
- OR8B4 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.52); catalogued as rs752372117, COSV62070702; called by muse, mutect2, varscan2
- OR8K5 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376114385, COSV100537278; called by muse, mutect2, varscan2
- OSBPL5 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 153/468 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55141042; called by muse, mutect2, varscan2
- OTOGL | c.5797G>A p.E1933K (on ENST00000547103; = p.E1924K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/200 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756958173, COSV54017465; called by muse, mutect2, varscan2
- PAK2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 148/342 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59080200; called by muse, mutect2
- PAK4 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 499/836 reads (60%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs770215974; called by muse, mutect2, varscan2
- PAK5 | c.2060A>G p.Q687R | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100781661; called by muse, mutect2
- PAK5 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 258/375 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as COSV62037795; called by muse, mutect2, varscan2
- PAK5 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 123/399 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV62031841; called by muse, mutect2, varscan2
- PAPPA2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 277/418 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV62774642; called by muse, mutect2, varscan2
- PAPPA2 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 144/446 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs775169340, COSV62776814, COSV62779600; called by muse, mutect2, varscan2
- PARP6 | c.1861C>G p.R621G | Missense Mutation (SNP) | VAF 105/443 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53002555; called by muse, mutect2, varscan2
- PARP9 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 222/479 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs1478334042; called by muse, mutect2, varscan2
- PAX6 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 131/407 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs1411880763; called by muse, mutect2, varscan2
- PAX8 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 227/378 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1164452252, COSV99640108; called by muse, mutect2, varscan2
- PCARE | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 147/424 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs759269733, COSV100527676, COSV59053819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH15 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 111/216 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as CM142134, COSV57306770; called by muse, mutect2, varscan2
- PCDH15 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 80/144 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488054571, COSV57348197; called by muse, mutect2, varscan2
- PCDHA1 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 212/621 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65374439; called by muse, mutect2, varscan2
- PCDHA4 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 210/655 reads (32%) | catalogued as COSV100793088; called by muse, mutect2, varscan2
- PCDHA8 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 168/434 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs782556523; called by muse, mutect2, varscan2
- PCDHA9 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 288/472 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV65323835; called by muse, mutect2, varscan2
- PCDHB12 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 257/708 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV53395531; called by muse, mutect2, varscan2
- PCDHB3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 125/392 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.108); catalogued as COSV50585999; called by muse, mutect2, varscan2
- PCDHB8 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 278/467 reads (60%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.582); catalogued as COSV50754695; called by muse, mutect2, varscan2
- PCDHGA12 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 422/683 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52760881; called by muse, mutect2, varscan2
- PCLO | c.15236C>T p.S5079L | Missense Mutation (SNP) | VAF 202/421 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs750960950, COSV61623630, COSV61653389; called by muse, mutect2, varscan2
- PCLO | c.11044C>T p.P3682S | Missense Mutation (SNP) | VAF 192/420 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201832967; called by muse, mutect2, varscan2
- PCLO | c.10930G>A p.E3644K | Missense Mutation (SNP) | VAF 177/366 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61615258; called by muse, mutect2, varscan2
- PCLO | c.8896C>T p.R2966C | Missense Mutation (SNP) | VAF 256/511 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173009964, COSV61649863; called by muse, mutect2, varscan2
- PCLO | c.6328G>T p.V2110F | Missense Mutation (SNP) | VAF 220/434 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV61617039; called by mutect2, varscan2
- PCLO | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 269/551 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.187); catalogued as COSV61617770; called by muse, mutect2, varscan2
2,805 further variants in this file (1,488 protein-altering or splice-affecting, 1,191 silent, 126 other) are not listed here.
